Somatic mutation profile of tumor specimen MMRF_2409_1_BM_CD138pos (aliquot MMRF_2409_1_BM_CD138pos_T1_KHS5U_K15211) from MMRF case MMRF_2409, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,436 days).
Specimen MMRF_2409_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e440ef0-2839-4f5d-a16b-16e8b04256a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2409_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2409_1_PB_Whole_C2_KHS5U_K15210; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80ab60bd-d9b7-416a-a334-dad9d188ae3d

The open-access MAF lists 138 somatic variants for this specimen: 51 protein-altering or splice-affecting, 23 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 34, Silent 23, Intron 19, 5'UTR 4, Nonsense Mutation 3, 5'Flank 3, RNA 2, 3'Flank 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A3 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53412559; called by muse, mutect2
- FAM135A | c.1638G>C p.Q546H | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99525953; called by muse, mutect2
- HIVEP1 | c.8006C>T p.S2669F | Missense Mutation (SNP) | VAF 113/444 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV65103811; called by muse, mutect2, varscan2
- IGDCC3 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 251/388 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1454719478, COSV60078319; called by muse, mutect2, varscan2
- IGHD3-9 | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 34/35 reads (97%) | catalogued as rs369734836; called by muse, varscan2
- IGHV2-70 | c.68T>A p.L23* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as rs189702615; called by muse, varscan2
- IRS2 | c.2718G>T p.E906D | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV65480081; called by muse, mutect2, varscan2
- KDM6B | c.1295T>C p.V432A | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1171216554; called by muse, mutect2
- KLHL4 | c.385A>C p.M129L | Missense Mutation (SNP) | VAF 47/47 reads (100%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.005); catalogued as COSV100909888; called by muse, mutect2, varscan2
- KMT2D | c.11158C>T p.Q3720* | Nonsense Mutation (SNP) | VAF 48/136 reads (35%) | catalogued as COSV56493334, COSV99982602; called by muse, varscan2
- LTO1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.049); catalogued as rs1270452510; called by muse, mutect2
- MAN2B2 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99578234; called by muse, mutect2, varscan2
- ME1 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs374166701; called by muse, mutect2, varscan2
- MRM3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs761278369, COSV58680856; called by muse, mutect2, varscan2
- MXRA5 | c.2459C>A p.P820H | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.615); catalogued as COSV54233139; called by muse, mutect2
- PCDHGA5 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.022); catalogued as COSV99545687; called by muse, mutect2
- PHLDB1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100616575; called by muse, mutect2
- PKD1L1 | c.5848C>T p.R1950C | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs150562937; called by muse, mutect2, varscan2
- TIAM2 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.023); catalogued as rs566475746; called by muse, mutect2, varscan2
- WRAP53 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs375033488; called by muse, mutect2, varscan2
- ZNF687 | c.3338G>A p.R1113H | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200803627, COSV99649531; called by muse, mutect2, varscan2
- ZNF775 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.443); catalogued as COSV100301426; called by muse, mutect2
- ADGRD2 | c.2426T>G p.M809R | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ALK | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- B4GALT7 | c.622A>T p.K208* | Nonsense Mutation (SNP) | VAF 15/261 reads (6%) | called by muse, mutect2
- CHRNA6 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRB1 | c.974G>C p.C325S | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2
- DUS2 | c.173-2A>G p.X58_splice | Splice Site (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- EGF | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2
- GCC2 | c.1682T>A p.I561K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- HIVEP1 | c.2237A>C p.E746A | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPU | c.1182C>G p.F394L (on ENST00000283179; = p.F456L on NM_004501.3) | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LCLAT1 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- LRRK1 | c.4045A>G p.N1349D | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.131); called by muse, mutect2
- MAP1A | c.4960T>G p.S1654A | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MEGF10 | c.1609A>T p.N537Y | Missense Mutation (SNP) | VAF 73/338 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- MUC16 | c.25132G>A p.A8378T | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NCAM2 | c.2018G>A p.G673E | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NR1D2 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR7D2 | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PSMD1 | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RLF | c.3154A>G p.K1052E | Missense Mutation (SNP) | VAF 115/232 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SCG2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SENP3 | c.1479+1G>A p.X493_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- SLC2A10 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SSH1 | c.2804G>A p.S935N | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SVOPL | c.289T>A p.Y97N | Missense Mutation (SNP) | VAF 15/391 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2
- TNFSF8 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 129/541 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- UACA | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- USP10 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 174/234 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB7A | c.1063T>C p.Y355H | Missense Mutation (SNP) | VAF 19/553 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); called by muse, mutect2
- C1S | c.156C>G p.L52= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV61071245; called by muse, mutect2, varscan2
- CARNS1 | c.1497C>T p.R499= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- CLOCK | c.303A>G p.K101= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs751422914; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A2 | c.3033C>T p.F1011= | Silent (SNP) | VAF 24/374 reads (6%) | catalogued as rs552124568; called by muse, mutect2
- DENND4C | c.5490A>C p.P1830= (on ENST00000434457 / NM_001330640.2; = p.P1781= on NM_017925.7) | Silent (SNP) | VAF 14/414 reads (3%) | called by muse, mutect2
- EHD3 | c.87C>T p.Y29= | Silent (SNP) | VAF 132/295 reads (45%) | catalogued as rs759507833, COSV59029638; called by muse, mutect2, varscan2
- HIVEP1 | c.7758T>A p.T2586= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- IFNAR2 | c.153C>T p.I51= | Silent (SNP) | VAF 475/728 reads (65%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.264G>C p.T88= | Silent (SNP) | VAF 186/197 reads (94%) | catalogued as rs11557982; called by muse, mutect2
- IGHV2-70 | c.201G>A p.E67= | Silent (SNP) | VAF 95/170 reads (56%) | catalogued as rs148856487; called by muse, varscan2
- KIRREL3 | c.543C>T p.I181= | Silent (SNP) | VAF 26/337 reads (8%) | called by muse, mutect2
- MMP12 | c.396C>T p.Y132= | Silent (SNP) | VAF 63/324 reads (19%) | catalogued as rs199918414; called by muse, mutect2, varscan2
- OR52M1 | c.636G>C p.L212= | Silent (SNP) | VAF 21/234 reads (9%) | called by muse, mutect2
- RBM15 | c.2490G>A p.K830= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.1029C>T p.S343= (on ENST00000321367; = p.S296= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/180 reads (51%) | called by muse, mutect2, varscan2
- SERPINI2 | c.606T>C p.N202= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as COSV52988009; called by muse, mutect2, varscan2
- TBX2 | c.189G>A p.A63= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- TEX2 | c.993G>A p.L331= | Silent (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- TNFRSF10D | c.78G>A p.S26= | Silent (SNP) | VAF 131/232 reads (56%) | called by muse, mutect2, varscan2
- TUBG1 | c.231C>T p.I77= | Silent (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- UBQLN1 | c.822C>T p.R274= | Silent (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- WDR17 | c.60A>G p.L20= | Silent (SNP) | VAF 66/124 reads (53%) | catalogued as rs752096305; called by muse, mutect2, varscan2
- WDR93 | c.1174C>T p.L392= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV99175437; called by muse, mutect2, varscan2
- AC004899.2 | n.149C>T | RNA (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2, varscan2
- AC083864.1 | n.740C>G | RNA (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- ACP4 | chr19:50798234 T>C | 3'Flank (SNP) | VAF 24/408 reads (6%) | catalogued as rs763558910; called by muse, mutect2
- APTX | chr9:32972709 T>C | 3'Flank (SNP) | VAF 49/223 reads (22%) | catalogued as rs759110975; called by muse, mutect2, varscan2
- ASPN | c.*910C>T | 3'UTR (SNP) | VAF 34/150 reads (23%) | catalogued as rs910554033; called by muse, mutect2, varscan2
- BRAP | c.-109C>G | 5'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- CCK | c.*33A>G | 3'UTR (SNP) | VAF 18/281 reads (6%) | called by muse, mutect2
- CDH19 | c.*1351T>G | 3'UTR (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2372G>T | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- CNIH3 | c.-610G>A | 5'UTR (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- COL24A1 | c.*444T>A | 3'UTR (SNP) | VAF 36/53 reads (68%) | called by muse, mutect2, varscan2
- COX7A2L | c.*1290T>C | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2
- CPE | c.*334A>G | 3'UTR (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- CTSA | chr20:45891059 G>A | 5'Flank (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- CYP11B1 | c.*1873C>T | 3'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- CYP4F3 | c.199-1681C>A | Intron (SNP) | VAF 337/534 reads (63%) | catalogued as rs1400855891; called by muse, mutect2, varscan2
- DDX4 | c.*526C>T | 3'UTR (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- DEPDC7 | c.73+250C>G | Intron (SNP) | VAF 12/419 reads (3%) | called by muse, mutect2
- EPHA3 | c.*1445C>A | 3'UTR (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- EXOG | c.313+1046G>A | Intron (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- FAM189A1 | c.*1418A>G | 3'UTR (SNP) | VAF 17/298 reads (6%) | called by muse, mutect2
- FHIT | c.*571T>C | 3'UTR (SNP) | VAF 6/106 reads (6%) | catalogued as rs1250866132; called by muse, mutect2
- GABRE | c.1138-66A>C | Intron (SNP) | VAF 40/808 reads (5%) | called by muse, mutect2
- GABRG3 | c.-48C>T | 5'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- GLRX5 | chr14:95533696 G>C | 5'Flank (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- HM13 | c.*326G>A | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- HNF4A | c.*554G>A | 3'UTR (SNP) | VAF 45/280 reads (16%) | called by muse, mutect2, varscan2
- HTRA3 | c.1051+1642G>A | Intron (SNP) | VAF 27/88 reads (31%) | catalogued as rs560019755; called by muse, mutect2, varscan2
- IKZF2 | c.406+91G>A | Intron (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- IQSEC3 | c.*2490G>C | 3'UTR (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- KCNQ5 | c.*2607A>T | 3'UTR (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- KLHL4 | c.*1946T>C | 3'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- LRRC14 | c.-111-33C>T | Intron (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- LRRC38 | c.-212G>A | 5'UTR (SNP) | VAF 23/52 reads (44%) | catalogued as rs1167925913; called by muse, mutect2, varscan2
- LRRC8C | c.*3832A>G | 3'UTR (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- LSS | c.*38+759A>G | Intron (SNP) | VAF 124/502 reads (25%) | called by muse, mutect2, varscan2
- MACF1 | c.16491+494C>G | Intron (SNP) | VAF 97/208 reads (47%) | called by muse, mutect2, varscan2
- MAP3K21 | c.1675+579T>C | Intron (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- MAP3K3 | c.126+1933C>G | Intron (SNP) | VAF 65/176 reads (37%) | called by muse, mutect2, varscan2
- MAPRE2 | c.*1778_*1779insGGTCTGCCG | 3'UTR (INS) | VAF 35/91 reads (38%) | called by mutect2, pindel, varscan2
- MYF5 | c.*197T>C | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- NFYC | c.885+98C>G | Intron (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- NPAS4 | c.945-55C>T | Intron (SNP) | VAF 28/354 reads (8%) | called by muse, mutect2
- PCDH11X | c.*1493A>T | 3'UTR (SNP) | VAF 24/437 reads (5%) | called by muse, mutect2
- PCMTD1 | c.*1864T>A | 3'UTR (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- PDLIM4 | c.506+85C>T | Intron (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- PLOD2 | c.*597G>T | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- PPME1 | c.*702G>C | 3'UTR (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- PSTPIP2 | c.354+17T>C | Intron (SNP) | VAF 16/201 reads (8%) | called by muse, mutect2
- RPS26 | c.*202_*203insA | 3'UTR (INS) | VAF 6/29 reads (21%) | called by pindel, varscan2*
- SHMT1 | c.1055-73G>A | Intron (SNP) | VAF 5/77 reads (6%) | catalogued as rs936419075; called by muse, mutect2
- SLC35E4 | c.*610T>C | 3'UTR (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- SLC7A1 | c.*473G>A | 3'UTR (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- ST6GALNAC5 | c.*227A>G | 3'UTR (SNP) | VAF 46/60 reads (77%) | called by muse, mutect2, varscan2
- TENM2 | c.*96G>T | 3'UTR (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- TFAP2B | chr6:50818749 T>A | 5'Flank (SNP) | VAF 66/172 reads (38%) | called by muse, mutect2, varscan2
- TMEM70 | c.316+43T>G | Intron (SNP) | VAF 25/216 reads (12%) | called by muse, mutect2, varscan2
- TRDN | c.*289G>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- UBE2NL | c.*109C>A | 3'UTR (SNP) | VAF 35/470 reads (7%) | catalogued as rs1312433060; called by muse, mutect2
- UGT2A3 | c.*688dup | 3'UTR (INS) | VAF 14/44 reads (32%) | catalogued as rs1189384567; called by mutect2, varscan2
- UTP14A | c.102+117G>T | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- ZNF155 | c.15+1482G>T | Intron (SNP) | VAF 24/78 reads (31%) | catalogued as rs757566963; called by muse, mutect2, varscan2
- ZNF488 | c.*2166C>T | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- ZNF84 | c.*1813T>A | 3'UTR (SNP) | VAF 6/109 reads (6%) | called by muse, mutect2
